Gene-level copy-number profile of specimen HCM-SANG-1327-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-1327-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1327-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78f149ab-0405-426c-a125-480098aa7ca9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1327-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/fdeb2efc-b25c-4f48-bd14-cd9c654ee967

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 5,290; copy number 2: 35,990; copy number 3: 11,940; copy number 4: 3,456; copy number 5: 332; copy number 6: 8; copy number 7: 1,357.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:8,116,745–8,116,949, 1 gene: SNRPCP17.
- chr9:41,276,280–41,282,846, 2 genes: PTGER4P2-CDK2AP2P2, CDK2AP2P1.
- chr14:50,632,058–50,962,002, 13 genes (within-gene range 0–1): SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,534 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–144,401,355, 37 genes, copy number 5–7: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4.
- chr2:68,945,232–68,952,893, 1 gene, copy number 5: GKN2.
- chr7:135,853–2,242,215, 53 genes, copy number 5 (within-gene range 4–5): AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655.
- chr7:5,103,719–5,425,414, 6 genes, copy number 5 (within-gene range 4–5): OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18.
- chr7:6,663,974–6,930,835, 14 genes, copy number 5: AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2, CCZ1B, OR7E39P, UNC93B2, OR7E136P, OR7E59P, AC079804.2, ALG1L5P, AC079804.1.
- chr7:8,433,609–8,939,369, 2 genes, copy number 5: NXPH1, AC009500.1.
- chr7:12,469,621–12,542,222, 1 gene, copy number 5 (within-gene range 4–5): AC013470.2.
- chr7:12,506,007–13,751,920, 11 genes, copy number 5: AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2.
- chr7:15,200,317–15,562,015, 1 gene, copy number 5: AGMO.
- chr7:16,087,525–16,888,885, 18 genes, copy number 5: CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2.
- chr7:16,938,225–16,938,557, 1 gene, copy number 5: AC098592.1.
- chr7:17,033,089–17,205,928, 2 genes, copy number 5: BRWD1P3, Metazoa_SRP.
- chr7:17,790,761–17,940,501, 1 gene, copy number 5: SNX13.
- chr7:19,695,461–21,401,613, 27 genes, copy number 5: POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P, AC005094.1.
- chr7:22,725,395–22,773,993, 4 genes, copy number 5: IL6-AS1, IL6, MTCYBP42, AC073072.1.
- chr7:38,722,974–40,099,580, 23 genes, copy number 5: VPS41, POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13.
- chr7:54,419,444–54,420,328, 1 gene, copy number 5: SLC25A5P3.
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
